Somatic mutation profile of tumor specimen TCGA-06-5411-01A (aliquot TCGA-06-5411-01A-01D-1696-08) from TCGA case TCGA-06-5411, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.6 years (18,832 days).
Specimen TCGA-06-5411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15e81798-49f4-4c67-9821-cb06d43ff28e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5411-10A (Blood Derived Normal), aliquot TCGA-06-5411-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63fbb9a5-d153-48d0-8be9-60db3c39e595

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 22, Silent 10, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 22/75 reads (29%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1BG | c.1397G>A p.G466D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996999776, COSV54050377; called by muse, mutect2, varscan2
- ABI2 | c.775C>T p.R259* (on ENST00000295851 / NM_001375719.1; = p.R253* on NM_005759.7 and 35 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | catalogued as COSV53690802; called by muse, mutect2, varscan2
- ADGRA2 | c.2389T>C p.S797P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as COSV55103135; called by muse, mutect2, varscan2
- ANO9 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.329); catalogued as rs1208623251, COSV60382945; called by muse, mutect2, varscan2
- ARHGEF28 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as rs780928597, COSV55262423; called by muse, mutect2, varscan2
- ARL9 | c.680G>A p.G227E (on ENST00000640821 / NM_001363794.2; = p.G85E on NM_206919.2) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63991399; called by muse, mutect2, varscan2
- CARD6 | c.1784T>A p.I595N | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as rs1273492433, COSV54565143; called by muse, mutect2, varscan2
- CBR1 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51738600; called by muse, mutect2, varscan2
- DNAH7 | c.9121G>A p.E3041K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753140811, COSV56774194; called by muse, mutect2, varscan2
- DSG4 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775608448, COSV57389793, COSV57393392; called by muse, mutect2, varscan2
- GABRA6 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.201); catalogued as rs762584200, COSV50879024; called by muse, mutect2, varscan2
- KIF16B | c.3574G>A p.V1192I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs746166094, COSV61709502; called by muse, mutect2, varscan2
- LOXL2 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101207967; called by muse, mutect2
- MASP2 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53569469; called by muse, mutect2, varscan2
- NPAP1 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as COSV61505649; called by muse, mutect2, varscan2
- NRIP1 | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59658772; called by mutect2, varscan2
- OR4D11 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 30/152 reads (20%) | catalogued as COSV57585139; called by muse, mutect2, varscan2
- OR6V1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.047); catalogued as COSV69237479; called by muse, mutect2, varscan2
- PCK1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368269624; called by muse, mutect2, varscan2
- PIGF | c.605T>C p.I202T | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV53189699; called by muse, mutect2, varscan2
- TLX3 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV51541004; called by muse, mutect2, varscan2
- TTLL11 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV58644401; called by muse, mutect2, varscan2
- TTLL11 | c.884A>T p.Q295L | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV58644417; called by muse, mutect2, varscan2
- TCF15 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEACAM20 | c.1485G>A p.K495= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV57602200, COSV57602418; called by muse, mutect2, varscan2
- DNAH11 | c.8361C>T p.C2787= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100179345, COSV60966253; called by muse, mutect2
- EVA1A | c.132C>T p.I44= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs759948119, COSV52057582; called by muse, mutect2, varscan2
- KIT | c.2145C>T p.S715= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs192110951, COSV55410571; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMAN1 | c.799T>C p.L267= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV51826380; called by muse, mutect2, varscan2
- MUC7 | c.156A>G p.L52= | Silent (SNP) | VAF 38/160 reads (24%) | catalogued as COSV59217729; called by muse, mutect2, varscan2
- MYF6 | c.222C>T p.P74= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs1355789333, COSV57350996, COSV57351164; called by muse, mutect2, varscan2
- OR2C3 | c.537T>C p.F179= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV63574697; called by muse, mutect2, varscan2
- RSPH10B | c.1641C>G p.L547= | Silent (SNP) | VAF 23/206 reads (11%) | catalogued as COSV100521382; called by muse, mutect2
- TEX15 | c.7152G>A p.T2384= (on ENST00000256246; = p.T2767= on NM_001350162.2) | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as rs369884354; called by muse, mutect2, varscan2
